Surgical pathology report (de-identified scan), TCGA case TCGA-EY-A1GI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of North Carolina, specimen TCGA-EY-A1GI-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

100-0-3

Adenocarcinoma, endometrioid, NOS 8380/3

Site: Endometrium C54.1

1/31/11 lw

Case Number :

Diagnosis:

A: Uterus, radical hysterectomy and bilateral salpingo-oophorectomy

Cervix

- No tumor seen

Endometrium

- Moderately differentiated endometrioid adenocarcinoma, overall FIGO grade 2 (architectural grade 2, nuclear grade 2) (A9)

- Tumor invades into the outer half of the myometrial wall to 1.3 cm out of 1.7 cm in total myometrial wall thickness (76%) (A12)

- Tumor involves the lower uterine segment mucosa only

- Focal lymphovascular space invasion present (A15)

- Tumor necrosis with acute inflammation present

- ER and PR, by immunohistochemistry, previously performed (see)

- AJCC pathologic staging: pT1c pN0 pMx

- FIGO stage grouping: IB

Myometrium

- See diagnoses above

B: Lymph node, right pelvic, removal

- Sixteen lymph nodes, no tumor seen (0/16)

C: Lymph node, left pelvic, removal

- Seven lymph nodes, no tumor seen (0/7)

Clinical History:

undergoing a radical hysterectomy, bilateral salpingo-oophorectomy and bilateral pelvic lymphadenectomy.

Gross Description:

Received are three appropriately labeled containers.

Container A:

Adnexa: present bilaterally

[page 2 of 3]
Weight: 201.1 grams

Shape: pear shaped

Dimensions:

height: 11.5 cm

anterior to posterior width: 5.5 cm

breadth at fundus: 6.5 cm

Serosa: tan, shiny and fibrous

Cervix: tan and white with an associated vaginal cuff extending 0.8 to 1.3 cm from the cervix

length of endocervical canal: approximately 1 cm

ectocervix: approximately 0.2 cm

endocervix: approximately 0.8 cm

Endomyometrium:

length of endometrial cavity: roughly 6.5 cm

width of endometrial cavity at fundus: 2.5 cm

tumor findings:

dimensions: Tumor is roughly circumferential and measures approximately 6 cm from cervical to fundic and approximately 3.3 cm in width

appearance: lobulated and white/tan

location and extent: The tumor occupies the majority of the endometrial cavity extending down close to the cervical canal

myometrial invasion: outer one-half

thickness of myometrial wall at deepest gross invasion: 1.1 cm

other findings or comments: none

Adnexa:

Right ovary:

dimensions: 2.2 x 1.8 x 0.6 cm

external surface: light tan and lobulated

cut surface: fibrous and white to pale yellow

Right fallopian tube:

dimensions: 4.0 x 0.6 cm

other findings: none

Left ovary:

dimensions: 3.0 x 1.6 x 0.7 cm

external surface: white/tan and lobulated

cut surface: fibrous and white to pale yellow

Left fallopian tube:

dimensions: 4.4 x 0.6 cm

other findings: benign appearing simple cyst

Lymph nodes: See Specimens B and C

Other comments: none

Digital photograph taken: no

Tissue submitted for special investigations: no

[page 3 of 3]
Block Summary:

A1 - right parametrial tissue
A2 - left parametrial tissue
A3 - anterior vaginal cuff, en face
A4 - posterior vaginal cuff, en face
A5 - anterior cervix
A6 - right cervix
A7 - left cervix
A8 - posterior cervix
A9 - anterior lower uterine segment
A10 - anterior mid corpus
A11 - anterior fundus
A12 - posterior lower uterine segment
A13 - posterior mid corpus
A14,A15 - posterior upper corpus, one section bisected
A16 - right ovary and fallopian tube
A17 - left ovary and fallopian tube

Container B is additionally labeled "right pelvic LN." The specimen consists of fibrofatty tissue measuring 5.0 x 5.0 x 1.5 cm. Six lymph node candidates are identified, the largest measuring 2.2 x 1.0 x 0.6 cm.

Block Summary:

B1 - two lymph node candidates
B2 - one lymph node candidate, bisected
B3 - remainder of lymph node candidates
B4-B10 - remainder of fibrofatty tissue, "

Container C is additionally labeled "L pelvic." The specimen consists of fibrofatty tissue measuring 4.5 x 4.0 x 1.7 cm. Four lymph node candidates are identified, the largest measuring 2.0 x 2.0 x 0.6 cm.

Block summary:

C1,C2 - largest lymph node candidate, bisected
C3 - remainder of lymph node candidates
C4-C6 - remainder of fibrofatty tissue,

Light Microscopy:

Light microscopic examination is performed by Dr.

Signature

Resident Physician:

Attending Pathologist: I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file d846e71f-5728-40e7-b2a9-06e17cda8306 (TCGA-EY-A1GI.1D56F7CA-A3F0-4078-B8E3-A10CD97873D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).